Gene-level copy-number profile of tumor specimen TCGA-04-1338-01A from TCGA case TCGA-04-1338, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 78.8 years (28,789 days).
Specimen TCGA-04-1338-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8fee54d4-4bfb-487a-94b3-be40b1e5f416.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1338-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/44d905d8-d047-40ad-b2a8-d437560bf39e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,731; copy number 2: 23,284; copy number 3: 17,630; copy number 4: 8,529; copy number 5: 3,626; copy number 6: 1,223; copy number 7: 481; copy number 8: 281; copy number 9: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-04-1338-01): tumor purity 0.74, ploidy 2.99, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,629 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,259,727–205,357,090, 1,154 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:38,814–4,140,731, 71 genes, copy number 5 (broad region; genes not listed).
- chr2:12,411,398–17,817,798, 56 genes, copy number 5: RNU6-843P, AC096559.1, AC009486.2, AC009486.1, TRIB2, MIR3125, AC064875.1, AC093912.1, AC073062.1, LINC00276, AC016730.1, RNU6-1288P, Metazoa_SRP, AC011897.1, LRATD1, AC068286.2, AC068286.1, NBAS, RPS26P18, AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1, MSGN1.
- chr3:62,779,176–66,038,834, 39 genes, copy number 5 (within-gene range 4–5): AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2, LINC02040, MAGI1, AC121493.1, ILF2P1.
- chr3:120,596,328–123,028,605, 51 genes, copy number 5: NDUFB4, HGD, RABL3, MTCO1P29, MTCO2P29, GTF2E1, NAP1L1P3, AC072026.2, LINC02049, AC072026.3, STXBP5L, AC072026.1, MIR5682, AC078857.1, AC079841.1, AC079841.2, POLQ, RPL7AP11, ARGFX, FBXO40, HCLS1, RN7SL172P, RNU4-62P, GOLGB1, IQCB1, EAF2, SLC15A2, ILDR1, Y_RNA, CD86, AC068630.1, CASR, HNRNPA1P23, CSTA, CCDC58, FAM162A, WDR5B, AC083798.2, AC083798.1, KPNA1, AC096861.1, AC096861.2, PARP9, DTX3L, PARP15, EIF4BP8, PARP14, HSPBAP1, SLC49A4, LINC02035, SEMA5B.
- chr3:167,478,684–198,222,513, 610 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr4:85,990,007–87,391,188, 22 genes, copy number 5 (within-gene range 4–5): MAPK10, MAPK10-AS1, RN7SKP96, MIR4452, PTPN13, SLC10A6, AC093827.1, C4orf36, AC093827.2, AC093827.5, AC093827.3, AC093827.4, AFF1, TECRP1, KLHL8, AC092658.1, GAPDHP60, AC108516.1, MIR5705, HSD17B13, AC108516.2, HSD17B11.
- chr4:103,548,745–147,159,068, 553 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:391,752–2,917,733, 44 genes, copy number 6: IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1, AL359852.2, AL359852.1, LINC02521, LINC01600, MYLK4, WRNIP1, SERPINB1, SERPINB9P1, MIR4645, SERPINB9, AL133351.2, AL133351.1.
- chr6:35,118,071–54,625,488, 434 genes, copy number 5 (broad region; genes not listed).
- chr7:132,784,870–159,233,377, 612 genes, copy number 5–8 (broad region; genes not listed).
- chr8:50,762,460–51,321,118, 4 genes, copy number 6: CYCSP22, AC087272.1, AC090919.1, AC012413.1.
- chr8:51,435,602–51,436,509, 1 gene, copy number 6: BRIX1P1.
- chr8:75,120,409–145,066,685, 1,082 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr10:8,897,989–22,479,480, 218 genes, copy number 5 (broad region; genes not listed).
- chr10:29,289,061–34,815,325, 93 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:73,497,538–73,625,953, 1 gene, copy number 6 (within-gene range 4–6): USP54.
- chr10:73,625,996–79,316,528, 111 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr11:108,665,069–114,595,786, 143 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–4,774,184, 118 genes, copy number 5 (broad region; genes not listed).
- chr17:66,895,491–67,056,797, 5 genes, copy number 5: RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1.
- chr20:48,264,969–51,131,667, 77 genes, copy number 5 (broad region; genes not listed).
- chr20:53,738,728–60,814,211, 130 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,315. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
